Surgical pathology report (de-identified scan), TCGA case TCGA-77-8143, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-8143-01A (Primary Tumor).

[page 1 of 2]
Collected [REDACTED]

Histopathology Report

HISTORY
(L) UL-NSCLC.

MACROSCOPIC
Four specimens received:

1: The first specimen is labelled "(L) upper lobe" and consists of an upper lobectomy measuring 240 mm from superior to inferior x 100 x 35 mm. The bronchial soft tissue resection margin measures 80 x 35 mm. A bronchial resection margin measures 20 x 7 mm. Superior to the soft tissue resection margin there is a stapled margin measuring 70 mm in length. Within the apex there is a firm tumour measuring 63 x 50 x 48 mm. The overlying pleura is puckered. On sectioning the tumour is centrally necrotic and is well defined and cream to yellow and focally black. Tumour is > 10 mm from the stapled resection margin and 30 mm from the bronchial resection margin. After removal of staples the new resection margin has been inked black. The overlying pleura has also been inked black. [1A-bronchial resection margin; 1B-? hilar lymph nodes; 1C-tumour, inked resection margin after removal of staples and overlying pleura; 1D-1F tumour and pleura; 1G-tumour and adjacent normal appearing lung; 1H-RS of normal lung; 1I-tumour and adjacent bronchus. No definite bronchial origin is identified.]

2: The second specimen is labelled "pulmonary vein lymph node" and consists of a fatty piece of tissue measuring 10 x 7 x 3 mm. On bisecting a single lymph node measuring 3 mm in maximum extent is identified. [Submitted in toto-2A.]

3: The third specimen is labelled "No. 6 lymph node" and consists of a fatty piece of tissue measuring 35 x 30 x 8 mm. On sectioning two lymph nodes are identified. [3A-3B lymph nodes bisected, part of each lymph node in each cassette. [Lymph node submitted in toto.]

4: The fourth specimen is labelled "No. 10 lymph node" and consists of a lymph node measuring 16 x 7 x 5 mm. [Bisected in toto-4A.]

MICROSCOPIC

1: Sections show a moderately to poorly differentiated squamous cell carcinoma with areas of central necrosis and cystic change as well as areas of sclerosis. There is a moderately heavy lymphoplasmacytic infiltrate in tumour stroma. Tumour abuts but does not appear to invade the overlying pleura and the inked resection margin is clear of malignancy. No vascular, lymphatic or perineural invasion is identified. The bronchial resection margin shows focal squamous metaplasia but no evidence of malignancy. Uninvolved lung parenchyma shows emphysema. Peribronchial lymph nodes contain small silicotic nodules but there is no evidence of metastatic carcinoma.

[page 2 of 2]
Collected

Histopathology Report

2: Sections show an anthracotic node in which there is no evidence of malignancy.

3: Sections show a deposit of metastatic squamous cell carcinoma in one of the lymph nodes. There are also a few small silicotic nodules.

4: Sections show an anthracotic node in which there is no evidence of malignancy.

SUMMARY

Left upper lobectomy and lymph node sampling:
Moderately to poorly differentiated squamous cell carcinoma, 63 mm in diameter.
No pleural, vascular, lymphatic or perineural invasion identified. Squamous metaplasia at bronchial resection margin.
Metastasis in No. 6 lymph node.
Pathological stage T2N2.

Cc: Lung Cancer Registry

Source: NCI Genomic Data Commons file 310a48e0-d5cf-40da-906f-f6f03fce78e3 (TCGA-77-8143.11EBD546-0402-4047-9568-A148C382CD23.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).